Somatic mutation profile of tumor specimen MP2PRT-PAWCEE-TMP1-A (aliquot MP2PRT-PAWCEE-TMP1-A-1-0-D-A80M-36) from MP2PRT case MP2PRT-PAWCEE, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.8 years (1,737 days).
Specimen MP2PRT-PAWCEE-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 71292acc-f5fe-40bd-8691-69603bace57c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAWCEE-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAWCEE-NB1-A-1-0-D-A80M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b4b374e1-d5f8-4935-9f37-af352450a7ab

The open-access MAF lists 19 somatic variants for this specimen: 17 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 15, Silent 2, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.220G>A p.D74N | Missense Mutation (SNP) | VAF 61/938 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs760640852, CM045607, COSV58683415, COSV58688841; ClinVar: uncertain significance; called by muse, mutect2
- ABCG8 | c.787C>T p.R263W | Missense Mutation (SNP) | VAF 232/545 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs775957691; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAJC13 | c.488C>T p.S163L | Missense Mutation (SNP) | VAF 87/209 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as COSV53456504; called by muse, mutect2, varscan2
- GAL3ST1 | c.1147G>A p.G383R | Missense Mutation (SNP) | VAF 270/632 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.657); catalogued as COSV58892421; called by muse, mutect2, varscan2
- PSG11 | c.184C>A p.L62I | Missense Mutation (SNP) | VAF 178/357 reads (50%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.895); catalogued as rs1294843577; called by muse, mutect2, varscan2
- RYR2 | c.6613C>T p.R2205C | Missense Mutation (SNP) | VAF 121/427 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1558103888, COSV63720881; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCN2A | c.5704C>T p.R1902C | Missense Mutation (SNP) | VAF 115/231 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs367833365, CM034570; called by muse, mutect2, varscan2
- CKAP2L | c.1544T>A p.L515H | Missense Mutation (SNP) | VAF 199/493 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- FAM149B1 | c.567A>C p.L189F | Missense Mutation (SNP) | VAF 24/339 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.014); called by muse, mutect2
- GEN1 | c.1996G>T p.D666Y | Missense Mutation (SNP) | VAF 14/424 reads (3%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, mutect2
- GMEB1 | c.1235C>T p.P412L | Missense Mutation (SNP) | VAF 297/654 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.431); called by muse, mutect2, varscan2
- HELZ | c.4633C>G p.Q1545E | Missense Mutation (SNP) | VAF 18/484 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); called by muse, mutect2
- IGKV3-15 | chr2:89085175 GGA>AGGAGG | Missense Mutation (INS) | VAF 128/280 reads (46%) | called by pindel, varscan2*
- LRP1B | c.7334A>T p.D2445V | Missense Mutation (SNP) | VAF 181/428 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- NEMP2 | c.303C>G p.I101M | Missense Mutation (SNP) | VAF 27/330 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.035); called by muse, mutect2
- NOTUM | c.990C>T p.C330= | Splice Region (SNP) | VAF 214/441 reads (49%) | called by muse, mutect2, varscan2
- WDR81 | c.94dup p.R32Pfs*95 | Frame Shift Ins (INS) | VAF 363/941 reads (39%) | called by mutect2, pindel, varscan2
- EPB41L3 | c.567T>C p.Y189= | Silent (SNP) | VAF 113/235 reads (48%) | called by muse, mutect2, varscan2
- MYH9 | c.1347G>A p.G449= | Silent (SNP) | VAF 130/469 reads (28%) | called by muse, mutect2, varscan2
